Somatic mutation profile of tumor specimen C3L-04040-01 (aliquot CPT0232060007) from CPTAC case C3L-04040, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 77.3 years (28,241 days).
Specimen C3L-04040-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5eb24769-3bec-4909-8df7-1015edb9636a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-04040-31 (Blood Derived Normal), aliquot CPT0232220002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/414def5a-eab1-47d3-8520-73f830356a24

The open-access MAF lists 158 somatic variants for this specimen: 104 protein-altering or splice-affecting, 32 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 92, Silent 32, Intron 10, Nonsense Mutation 8, RNA 4, 5'UTR 3, Frame Shift Del 2, 3'Flank 2, Splice Site 2, 3'UTR 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 26/292 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- SF3B1 | c.2101G>T p.V701F | Missense Mutation (SNP) | VAF 14/75 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59206944, COSV59216146; called by muse, mutect2, varscan2
- AL031777.2 | c.405G>C p.W135C | Missense Mutation (SNP) | VAF 10/252 reads (4%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV100587258; called by muse, mutect2
- APOA5 | c.536G>T p.R179L | Missense Mutation (SNP) | VAF 23/223 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.248); catalogued as COSV57062401; called by muse, mutect2
- ARHGEF10 | c.3310G>T p.A1104S (on ENST00000398564; = p.A1079S on NM_014629.4) | Missense Mutation (SNP) | VAF 58/498 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs200108151; called by mutect2, varscan2
- BOD1L2 | c.255C>A p.D85E | Missense Mutation (SNP) | VAF 26/249 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.049); catalogued as COSV73996896; called by muse, mutect2
- C19orf12 | c.418G>T p.V140F (on ENST00000392278 / NM_001031726.3; = p.V129F on NM_031448.6) | Missense Mutation (SNP) | VAF 36/393 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.01); catalogued as COSV60364977; called by muse, mutect2
- CACNA1C | c.4025G>A p.R1342H | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1365999989, COSV59762077, COSV59778286; called by muse, mutect2
- CELSR2 | c.4108C>T p.R1370C | Missense Mutation (SNP) | VAF 21/408 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746383773, COSV54780478; called by muse, mutect2
- CHRM2 | c.1084G>A p.A362T | Missense Mutation (SNP) | VAF 35/288 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.304); catalogued as COSV57785134; called by muse, mutect2, varscan2
- CNTNAP2 | c.1197C>A p.F399L | Missense Mutation (SNP) | VAF 58/426 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as COSV62223172; called by muse, mutect2, varscan2
- CPEB4 | c.962T>A p.L321Q | Missense Mutation (SNP) | VAF 39/276 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.781); catalogued as COSV54169818; called by muse, mutect2, varscan2
- CSMD1 | c.6793G>T p.V2265F (on ENST00000520002; = p.V2264F on NM_033225.6) | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99064796; called by muse, mutect2, varscan2
- DCBLD1 | c.1972G>T p.A658S | Missense Mutation (SNP) | VAF 33/551 reads (6%) | SIFT tolerated (0.66); PolyPhen benign (0.02); catalogued as COSV99757674; called by muse, mutect2
- DHX30 | c.3224C>T p.T1075M (on ENST00000445061 / NM_138615.3; = p.T1036M on NM_014966.3) | Missense Mutation (SNP) | VAF 35/305 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV53140061; called by muse, mutect2, varscan2
- DICER1 | c.3787G>A p.G1263S | Missense Mutation (SNP) | VAF 26/562 reads (5%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0); catalogued as rs895397073; called by muse, mutect2
- DNHD1 | c.7237A>G p.I2413V | Missense Mutation (SNP) | VAF 50/444 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.04); catalogued as rs1342368005; called by muse, mutect2, varscan2
- ERICH3 | c.383C>A p.P128Q | Missense Mutation (SNP) | VAF 26/248 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.488); catalogued as COSV58601094; called by muse, mutect2
- FLII | c.1069G>C p.E357Q | Missense Mutation (SNP) | VAF 14/277 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as COSV100493804; called by muse, mutect2
- G6PC2 | c.171G>T p.M57I | Missense Mutation (SNP) | VAF 69/267 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as COSV56373556; called by muse, mutect2, varscan2
- GFRA3 | c.694C>A p.R232S | Missense Mutation (SNP) | VAF 31/193 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs1297911669; called by muse, mutect2, varscan2
- GRIN2A | c.58G>T p.G20C | Missense Mutation (SNP) | VAF 40/363 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.138); catalogued as rs779149309, COSV100410258; called by muse, mutect2, varscan2
- IGHM | c.677C>A p.A226D | Missense Mutation (SNP) | VAF 110/589 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.826); catalogued as rs1555378120; called by muse, mutect2, varscan2
- KRTAP13-1 | c.268A>G p.S90G | Missense Mutation (SNP) | VAF 63/375 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs1156269460; called by muse, mutect2, varscan2
- LMTK3 | c.600C>A p.C200* | Nonsense Mutation (SNP) | VAF 28/357 reads (8%) | catalogued as COSV99541351; called by muse, mutect2
- MMP12 | c.791A>C p.D264A | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs1265630887; called by muse, mutect2, varscan2
- NEB | c.16721C>G p.S5574C | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775485695; called by muse, mutect2, varscan2
- OR4C46 | c.205G>T p.A69S | Missense Mutation (SNP) | VAF 33/382 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.009); catalogued as rs1252951997, COSV60220693; called by muse, mutect2
- OR5D18 | c.865C>A p.L289M | Missense Mutation (SNP) | VAF 27/254 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV100450954, COSV61737830; called by muse, mutect2, varscan2
- PCDHGA10 | c.2244C>A p.D748E | Missense Mutation (SNP) | VAF 91/721 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.272); catalogued as COSV54006574; called by muse, mutect2, varscan2
- PCDHGA12 | c.1351G>T p.V451F | Missense Mutation (SNP) | VAF 20/235 reads (9%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.009); catalogued as rs768038692; called by muse, mutect2
- RARA | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 12/234 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV54190899; called by muse, mutect2
- RASL12 | c.341A>G p.E114G | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.222); catalogued as rs1291336525; called by muse, mutect2
- SCN10A | c.4736G>T p.R1579L | Missense Mutation (SNP) | VAF 26/343 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); catalogued as COSV71862155, COSV71862173; called by muse, mutect2
- SCN5A | c.5341G>T p.E1781* (on ENST00000333535 / NM_198056.3; = p.E1780* on NM_000335.5) | Nonsense Mutation (SNP) | VAF 61/564 reads (11%) | catalogued as rs1553692784, COSV61121698; called by muse, mutect2, varscan2
- SEMA5A | c.1493G>T p.G498V | Missense Mutation (SNP) | VAF 39/187 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV66793530, COSV66795928; called by muse, mutect2, varscan2
- SMC2 | c.1472G>T p.R491I | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.094); catalogued as COSV99659597; called by muse, mutect2
- SPANXD | c.83C>T p.T28I | Missense Mutation (SNP) | VAF 28/648 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV65152662; called by muse, mutect2
- SPATA31A6 | c.872G>T p.C291F | Missense Mutation (SNP) | VAF 76/1023 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV100253291; called by muse, mutect2
- ST6GAL2 | c.436G>T p.G146W | Missense Mutation (SNP) | VAF 14/136 reads (10%) | PolyPhen benign (0.43); catalogued as COSV64532905; called by muse, mutect2
- ST6GALNAC6 | c.71G>C p.R24P | Missense Mutation (SNP) | VAF 20/172 reads (12%) | PolyPhen possibly damaging (0.626); catalogued as rs764018000; called by muse, mutect2
- SYCP2L | c.1011+1G>T p.X337_splice | Splice Site (SNP) | VAF 16/134 reads (12%) | catalogued as rs766688684; called by muse, mutect2, varscan2
- TBC1D22A | c.168G>T p.K56N | Missense Mutation (SNP) | VAF 32/509 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.423); catalogued as COSV100452468; called by muse, mutect2
- TNFSF11 | c.721T>A p.Y241N | Missense Mutation (SNP) | VAF 49/459 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53476472; called by muse, mutect2, varscan2
- TRIM11 | c.1360A>G p.I454V | Missense Mutation (SNP) | VAF 42/186 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs572291808; called by mutect2, varscan2
- TRIM43 | c.62A>G p.Y21C | Missense Mutation (SNP) | VAF 92/523 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.33); catalogued as rs1332719680; called by muse, mutect2, varscan2
- TTC21A | c.499A>G p.I167V | Missense Mutation (SNP) | VAF 42/302 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.137); catalogued as rs1034214313, COSV100073232; called by muse, mutect2, varscan2
- TXNRD2 | c.235C>T p.R79W | Missense Mutation (SNP) | VAF 16/314 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as rs762060966, COSV57632035; called by muse, mutect2
- ABL1 | c.2008A>C p.N670H | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2
- AC104389.6 | c.422del p.G141Afs*16 | Frame Shift Del (DEL) | VAF 41/352 reads (12%) | called by mutect2, varscan2
- ACSM5 | c.1538T>A p.V513E | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.417); called by muse, mutect2
- ACTN2 | c.1823G>T p.R608L | Missense Mutation (SNP) | VAF 35/315 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADAMTS17 | c.2412G>T p.W804C | Missense Mutation (SNP) | VAF 46/412 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ARHGEF10L | c.2353T>G p.C785G | Missense Mutation (SNP) | VAF 26/280 reads (9%) | SIFT tolerated (0.49); PolyPhen benign (0.007); called by muse, mutect2
- CFHR1 | c.982G>C p.A328P | Missense Mutation (SNP) | VAF 58/290 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- CNTNAP2 | c.1198C>A p.Q400K | Missense Mutation (SNP) | VAF 59/432 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- COL14A1 | c.4062T>A p.Y1354* | Nonsense Mutation (SNP) | VAF 13/207 reads (6%) | called by muse, mutect2
- COL14A1 | c.4063G>T p.G1355* | Nonsense Mutation (SNP) | VAF 13/206 reads (6%) | called by muse, mutect2
- DCAF5 | c.2537A>G p.N846S | Missense Mutation (SNP) | VAF 33/361 reads (9%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); called by muse, mutect2
- DMXL1 | c.6256G>T p.A2086S | Missense Mutation (SNP) | VAF 28/153 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EVI5L | c.1494G>C p.E498D | Missense Mutation (SNP) | VAF 11/379 reads (3%) | SIFT tolerated (0.41); PolyPhen benign (0.101); called by muse, mutect2
- GABPA | c.899C>T p.P300L | Missense Mutation (SNP) | VAF 14/276 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.201); called by muse, mutect2
- GALNT11 | c.337G>T p.G113C | Missense Mutation (SNP) | VAF 14/245 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- GALNT11 | c.1459C>G p.H487D | Missense Mutation (SNP) | VAF 13/305 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.124); called by muse, mutect2
- GNL2 | c.832del p.T278Hfs*49 | Frame Shift Del (DEL) | VAF 10/78 reads (13%) | called by mutect2, varscan2
- GPAT3 | c.939G>A p.M313I | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- GREB1 | c.3761G>T p.R1254L | Missense Mutation (SNP) | VAF 55/334 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- HMCN1 | c.5684G>A p.R1895K | Missense Mutation (SNP) | VAF 26/576 reads (5%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.975); called by muse, mutect2
- HSPA8 | c.1844G>A p.G615E | Missense Mutation (SNP) | VAF 12/276 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- HTR7 | c.1063G>T p.G355C | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IGLV7-43 | c.47-1G>A p.X16_splice | Splice Site (SNP) | VAF 8/171 reads (5%) | called by muse, mutect2
- IL2RA | c.441G>A p.M147I | Missense Mutation (SNP) | VAF 46/496 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2
- INPP4B | c.1138G>T p.G380C | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITIH6 | c.1868A>T p.Q623L | Missense Mutation (SNP) | VAF 47/269 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- KAT6B | c.4537C>T p.Q1513* | Nonsense Mutation (SNP) | VAF 26/456 reads (6%) | called by muse, mutect2
- KRTAP10-7 | c.593C>T p.S198L | Missense Mutation (SNP) | VAF 40/928 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.801); called by muse, mutect2
- MFSD13A | c.1462C>T p.Q488* | Nonsense Mutation (SNP) | VAF 20/386 reads (5%) | called by muse, mutect2
- MON1A | c.1874C>T p.S625L | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MUC16 | c.18881C>T p.T6294I | Missense Mutation (SNP) | VAF 12/157 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.077); called by muse, mutect2
- MUC16 | c.6158G>T p.W2053L | Missense Mutation (SNP) | VAF 11/240 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2
- PAK1 | c.769T>G p.L257V | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- PBK | c.712T>A p.W238R | Missense Mutation (SNP) | VAF 40/288 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDHGA2 | c.75G>T p.E25D | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); called by muse, mutect2
- PIGR | c.1493G>A p.W498* | Nonsense Mutation (SNP) | VAF 30/516 reads (6%) | called by muse, mutect2
- PLXNA4 | c.3223G>A p.A1075T | Missense Mutation (SNP) | VAF 23/338 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.555); called by muse, mutect2
- PSG3 | c.394A>T p.R132* | Nonsense Mutation (SNP) | VAF 17/193 reads (9%) | called by muse, mutect2
- PXDNL | c.4178C>A p.A1393E | Missense Mutation (SNP) | VAF 20/292 reads (7%) | SIFT tolerated (0.61); PolyPhen benign (0.019); called by muse, mutect2
- R3HDM1 | c.72A>T p.K24N | Missense Mutation (SNP) | VAF 22/255 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.101); called by muse, mutect2
- RYR2 | c.13502A>G p.N4501S | Missense Mutation (SNP) | VAF 14/214 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- SFMBT2 | c.1927G>C p.V643L | Missense Mutation (SNP) | VAF 14/159 reads (9%) | SIFT tolerated (0.64); PolyPhen benign (0.069); called by muse, mutect2
- SLC6A5 | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 15/239 reads (6%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.007); called by muse, mutect2
- ST18 | c.2372G>T p.G791V | Missense Mutation (SNP) | VAF 42/315 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- STAT1 | c.895C>G p.Q299E | Missense Mutation (SNP) | VAF 62/527 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TMPRSS11E | c.1068G>A p.M356I | Missense Mutation (SNP) | VAF 27/240 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- TRIM47 | c.1211A>T p.E404V | Missense Mutation (SNP) | VAF 35/344 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- TRIT1 | c.49A>G p.R17G | Missense Mutation (SNP) | VAF 20/215 reads (9%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, mutect2
- UBAP2L | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- USP29 | c.1193G>T p.G398V | Missense Mutation (SNP) | VAF 17/199 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.251); called by muse, mutect2
- USP9Y | c.3305C>G p.P1102R | Missense Mutation (SNP) | VAF 21/163 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- YTHDF3 | c.230C>T p.S77F | Missense Mutation (SNP) | VAF 13/276 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- ZNF532 | c.1768A>T p.S590C | Missense Mutation (SNP) | VAF 13/177 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF804A | c.1144C>A p.H382N | Missense Mutation (SNP) | VAF 37/188 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF831 | c.2020C>A p.Q674K | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ZNHIT6 | c.170T>C p.I57T | Missense Mutation (SNP) | VAF 12/268 reads (4%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- ABCA12 | c.1797G>T p.V599= (on ENST00000272895 / NM_173076.3; = p.V281= on NM_015657.3) | Silent (SNP) | VAF 20/220 reads (9%) | called by muse, mutect2
- ADCY1 | c.3291C>G p.V1097= | Silent (SNP) | VAF 16/262 reads (6%) | catalogued as rs1240381144; called by muse, mutect2
- BOD1L2 | c.15C>T p.G5= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs1388303883; called by mutect2, varscan2
- CARS2 | c.1515C>T p.P505= | Silent (SNP) | VAF 30/662 reads (5%) | catalogued as rs763434479; called by muse, mutect2
- CDH13 | c.831C>A p.T277= | Silent (SNP) | VAF 10/87 reads (11%) | catalogued as COSV99227975; called by mutect2, varscan2
- CDH18 | c.447G>T p.V149= | Silent (SNP) | VAF 33/348 reads (9%) | called by muse, mutect2
- CSMD1 | c.6792G>A p.A2264= (on ENST00000520002; = p.A2263= on NM_033225.6) | Silent (SNP) | VAF 12/89 reads (13%) | catalogued as rs748899389; called by mutect2, varscan2
- DHDDS | c.828A>G p.T276= (on ENST00000236342 / NM_001319959.1; = p.T277= on NM_024887.3) | Silent (SNP) | VAF 42/338 reads (12%) | called by muse, mutect2, varscan2
- DOCK9 | c.2868G>A p.L956= (on ENST00000376460 / NM_001366676.2; = p.L957= on NM_015296.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/193 reads (5%) | catalogued as rs989634304, COSV100240796; called by muse, mutect2
- EXTL3 | c.87C>G p.L29= | Silent (SNP) | VAF 18/328 reads (5%) | called by muse, mutect2
- F10 | c.426G>A p.E142= | Silent (SNP) | VAF 24/450 reads (5%) | catalogued as rs144824590; called by muse, mutect2
- FTMT | c.273C>G p.S91= | Silent (SNP) | VAF 14/213 reads (7%) | called by muse, mutect2
- GABRA5 | c.1179C>G p.T393= | Silent (SNP) | VAF 44/385 reads (11%) | called by muse, mutect2, varscan2
- GCGR | c.534G>A p.A178= | Silent (SNP) | VAF 30/299 reads (10%) | catalogued as rs373859578; called by muse, mutect2, varscan2
- GPD1 | c.342T>A p.T114= | Silent (SNP) | VAF 37/389 reads (10%) | called by muse, mutect2
- HKDC1 | c.1389G>T p.V463= | Silent (SNP) | VAF 12/276 reads (4%) | called by muse, mutect2
- KCNJ15 | c.597A>T p.V199= | Silent (SNP) | VAF 9/252 reads (4%) | called by muse, mutect2
- MAGEL2 | c.774G>T p.P258= | Silent (SNP) | VAF 27/260 reads (10%) | catalogued as COSV58566466; called by muse, mutect2, varscan2
- NBAS | c.1572G>C p.T524= | Silent (SNP) | VAF 28/382 reads (7%) | catalogued as rs774185242, COSV55711175; called by muse, mutect2
- OR10V1 | c.69C>A p.V23= | Silent (SNP) | VAF 19/205 reads (9%) | called by muse, mutect2
- OR5B21 | c.75C>A p.L25= | Silent (SNP) | VAF 28/226 reads (12%) | called by muse, mutect2, varscan2
- PCDH18 | c.3396C>A p.V1132= | Silent (SNP) | VAF 6/39 reads (15%) | called by muse, mutect2, varscan2
- PRAMEF20 | c.375A>G p.L125= | Silent (SNP) | VAF 45/700 reads (6%) | called by muse, mutect2
- RDX | c.1257A>G p.A419= | Silent (SNP) | VAF 24/272 reads (9%) | called by muse, mutect2
- SIX4 | c.690C>T p.F230= | Silent (SNP) | VAF 13/301 reads (4%) | called by muse, mutect2
- SPTA1 | c.5892C>A p.L1964= | Silent (SNP) | VAF 35/440 reads (8%) | catalogued as COSV100935719, COSV63748168; called by muse, mutect2
- TMUB2 | c.174A>G p.V58= (on ENST00000538716 / NM_001353177.2; = p.V38= on NM_024107.3 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 32/307 reads (10%) | catalogued as rs1405053272; called by muse, mutect2
- TSHZ3 | c.1338C>A p.P446= | Silent (SNP) | VAF 18/246 reads (7%) | catalogued as COSV99550865; called by muse, mutect2
- WDR90 | c.186C>T p.T62= | Silent (SNP) | VAF 42/381 reads (11%) | called by muse, mutect2, varscan2
- XIRP2 | c.2694G>T p.V898= (on ENST00000628543; = p.V1073= on NM_152381.6) | Silent (SNP) | VAF 33/156 reads (21%) | called by muse, mutect2, varscan2
- ZDHHC18 | c.378C>T p.I126= | Silent (SNP) | VAF 12/242 reads (5%) | called by muse, mutect2
- ZNF536 | c.1596C>G p.A532= | Silent (SNP) | VAF 25/255 reads (10%) | catalogued as COSV62818019; called by muse, mutect2
- ATP6V0E1 | chr5:173020835 G>T | 3'Flank (SNP) | VAF 32/500 reads (6%) | called by muse, mutect2
- CCNQP1 | n.167C>A | RNA (SNP) | VAF 120/465 reads (26%) | called by muse, mutect2, varscan2
- CCSER1 | c.2094+23163G>T | Intron (SNP) | VAF 16/284 reads (6%) | catalogued as rs267600297, COSV61411328; called by muse, mutect2
- COL22A1 | c.-3G>T | 5'UTR (SNP) | VAF 26/279 reads (9%) | catalogued as rs968964706; called by muse, mutect2
- CXADRP2 | n.115T>A | RNA (SNP) | VAF 14/60 reads (23%) | called by mutect2, varscan2
- DLX1 | c.513+146C>T | Intron (SNP) | VAF 46/427 reads (11%) | called by muse, mutect2, varscan2
- GRSF1 | c.1257+45G>T | Intron (SNP) | VAF 11/139 reads (8%) | called by muse, mutect2
- HK1 | c.63+45C>G | Intron (SNP) | VAF 18/290 reads (6%) | called by muse, mutect2
- IGHV3-16 | c.-24G>A | 5'UTR (SNP) | VAF 34/212 reads (16%) | called by muse, mutect2, varscan2
- KCNIP2 | c.73+3702C>T | Intron (SNP) | VAF 17/218 reads (8%) | catalogued as rs771130162; called by muse, mutect2
- MANBA | c.549+22C>T | Intron (SNP) | VAF 36/371 reads (10%) | catalogued as rs576945794; called by muse, mutect2
- MIR6080 | chr17:64780099 C>T | 5'Flank (SNP) | VAF 18/472 reads (4%) | called by muse, mutect2
- NAMPTP1 | n.442G>C | RNA (SNP) | VAF 41/395 reads (10%) | called by muse, mutect2, varscan2
- RFX8 | c.-53+418A>G | Intron (SNP) | VAF 20/163 reads (12%) | called by muse, mutect2, varscan2
- RPGR | c.2520+209G>A | Intron (SNP) | VAF 26/89 reads (29%) | called by muse, mutect2, varscan2
- RTF2 | c.-21G>T | 5'UTR (SNP) | VAF 8/91 reads (9%) | called by muse, mutect2
- SLC11A2 | c.*1586A>T | 3'UTR (SNP) | VAF 22/165 reads (13%) | called by muse, mutect2, varscan2
- SMARCA4 | c.3546+9G>C | Intron (SNP) | VAF 34/352 reads (10%) | called by muse, mutect2
- SNORD116-22 | chr15:25092122 G>A | 3'Flank (SNP) | VAF 18/264 reads (7%) | catalogued as rs919542137; called by muse, mutect2
- TCEA2 | c.892-13C>G | Intron (SNP) | VAF 13/80 reads (16%) | called by muse, mutect2, varscan2
- TRAM2 | c.*5A>G | 3'UTR (SNP) | VAF 22/217 reads (10%) | called by muse, mutect2
- ZNF849P | n.768C>T | RNA (SNP) | VAF 42/213 reads (20%) | called by muse, mutect2, varscan2
